Somatic mutation profile of tumor specimen MP2PRT-PAPFBK-TMP1-A (aliquot MP2PRT-PAPFBK-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFBK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (865 days).
Specimen MP2PRT-PAPFBK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83e5772b-86d0-4296-b89f-887030ae4a97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFBK-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFBK-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c450046a-d52c-4e8d-afe6-9f2dfb03ea51

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPARGC1A | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as rs765593598; called by muse, mutect2, varscan2
- HAGHL | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 125/636 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- IGHV3-66 | chr14:106675012 GTGTCTCTC>TCCACA | Missense Mutation (DEL) | VAF 38/143 reads (27%) | called by pindel, varscan2*
- NLGN4Y | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PHTF2 | c.1576G>A p.E526K (on ENST00000248550 / NM_001366089.1; = p.E488K on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PPP4R3C | c.1974G>T p.K658N | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SCN2A | c.5786C>G p.S1929* | Nonsense Mutation (SNP) | VAF 13/281 reads (5%) | called by muse, mutect2
- SYCP1 | c.1119T>A p.H373Q | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ACACB | c.3513C>T p.I1171= | Silent (SNP) | VAF 19/401 reads (5%) | catalogued as rs1318964150; called by muse, mutect2
- AP5Z1 | c.1935C>T p.S645= | Silent (SNP) | VAF 56/331 reads (17%) | catalogued as rs759141046; called by muse, mutect2, varscan2
- BEST1 | c.1464G>A p.K488= | Silent (SNP) | VAF 61/398 reads (15%) | catalogued as rs1336067563; called by muse, mutect2, varscan2
- PTPRU | c.2916C>T p.F972= | Silent (SNP) | VAF 41/361 reads (11%) | called by muse, mutect2, varscan2
